CCDI case PBBSCL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/e137923f-7f0b-4518-b580-c9cf68e73815

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 18.3 years (6,690 days).

Biospecimens (3 samples)
- Sample 0DGDW4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGDWC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DGFW0: Tissue type: Tumor; Specimen type: Solid Tissue.
